Somatic mutation profile of tumor specimen TCGA-XF-A9T5-01A (aliquot TCGA-XF-A9T5-01A-11D-A42E-08) from TCGA case TCGA-XF-A9T5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.2 years (28,578 days).
Specimen TCGA-XF-A9T5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bb7764e-67f1-436a-8ce2-03e28c6c610d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-A9T5-10A (Blood Derived Normal), aliquot TCGA-XF-A9T5-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79a2bdc9-9f4a-4ad0-8189-961441f42ee4

The open-access MAF lists 776 somatic variants for this specimen: 567 protein-altering or splice-affecting, 185 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 491, Silent 185, Nonsense Mutation 57, Splice Site 10, Intron 9, Frame Shift Del 4, RNA 4, 5'Flank 4, 3'Flank 3, 3'UTR 3, Splice Region 2, Frame Shift Ins 1.

Variants (750 of 776; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | hotspot (GDC flag); catalogued as rs1362274408, COSV55920408; called by muse, mutect2, varscan2
- NALCN | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs878853133, CM151800, COSV51939068, COSV51951602; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASS | c.2543C>G p.S848C | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV62790963; called by muse, mutect2, varscan2
- ABHD3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as COSV56676289, COSV56677493, COSV56678649; called by muse, mutect2, varscan2
- AC244197.3 | c.465G>T p.R155S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV61713458; called by muse, mutect2, varscan2
- ACTL6B | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.805); catalogued as COSV50516736; called by muse, mutect2, varscan2
- ADA2 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV99375786; called by muse, mutect2, varscan2
- ADAMTS9 | c.4472G>A p.R1491K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55777396, COSV99898529; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2550G>C p.W850C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55003784; called by muse, mutect2
- ADAP1 | c.783G>C p.K261N | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1227210916, COSV56215881; called by muse, mutect2, varscan2
- ADARB2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as rs140367778; called by muse, mutect2
- ADCK2 | c.1269G>C p.K423N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as COSV50782464; called by muse, mutect2, varscan2
- ADGRA2 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV59440686, COSV59445620; called by muse, mutect2
- ADGRG2 | c.2337G>C p.W779C (on ENST00000379869 / NM_001079858.3; = p.W776C on NM_005756.4) | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61340296; called by muse, mutect2, varscan2
- ADGRG3 | c.1527C>G p.F509L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV59651886; called by muse, mutect2, varscan2
- ADGRV1 | c.6937C>T p.P2313S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406349587, COSV67990932; called by muse, mutect2, varscan2
- AFF3 | c.2758G>T p.D920Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV57863774; called by muse, mutect2, varscan2
- AFP | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.812); catalogued as COSV56926251; called by muse, mutect2, varscan2
- AGO1 | c.1086G>C p.M362I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV64595901; called by muse, mutect2, varscan2
- AGXT2 | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV51488599; called by muse, mutect2, varscan2
- AL645922.1 | c.2545C>T p.H849Y | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54961723; called by muse, mutect2, varscan2
- ALPK2 | c.1918C>G p.L640V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs908636501, COSV64494943, COSV64496563; called by muse, mutect2, varscan2
- ALX4 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV100240936; called by muse, mutect2
- AMZ1 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs753404311, COSV100406221; called by muse, varscan2
- ANKEF1 | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV65693008, COSV65693026; called by muse, mutect2, varscan2
- ANKH | c.704G>C p.R235T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV52483803; called by muse, mutect2
- ANKRD2 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.051); catalogued as rs1387105590, COSV100080731; called by muse, mutect2, varscan2
- ANLN | c.2761C>G p.H921D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV56078046; called by muse, mutect2, varscan2
- AP3B2 | c.2727C>G p.I909M (on ENST00000261722; = p.I903M on NM_004644.5) | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV55609808, COSV55612153; called by muse, mutect2, varscan2
- APBB2 | c.893G>A p.R298K (on ENST00000295974 / NM_001166050.2; = p.R299K on NM_004307.2) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV55957826; called by muse, mutect2, varscan2
- APBB3 | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262718156, COSV60053480; called by muse, mutect2, varscan2
- APLP1 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.062); catalogued as COSV55704092, COSV55705388; called by muse, mutect2, varscan2
- APOC3 | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99369156; called by muse, mutect2, varscan2
- APOL5 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1334547958, COSV50767761; called by muse, mutect2, varscan2
- ARFGEF1 | c.3328C>T p.Q1110* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as COSV99141280; called by muse, mutect2, varscan2
- ARHGAP17 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51510020; called by muse, varscan2
- ARHGAP22 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50958867; called by muse, mutect2, varscan2
- ARHGEF37 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs748153413, COSV61369530; called by muse, mutect2, varscan2
- ARID1A | c.1850C>G p.S617* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV61374388, COSV61381125; called by muse, mutect2, varscan2
- ARL4C | c.32T>A p.F11Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.842); catalogued as COSV100326789; called by muse, mutect2
- ARV1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as rs1161719116, COSV59618288; called by muse, mutect2, varscan2
- ASB2 | c.1527C>G p.I509M | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs146138244, COSV60114711; called by muse, mutect2, varscan2
- ASNSD1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs745921145, COSV53624386; called by muse, mutect2, varscan2
- ASPM | c.5786A>C p.Q1929P | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV54134308; called by muse, mutect2, varscan2
- ATG4C | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV58607209; called by muse, mutect2, varscan2
- ATM | c.7114G>A p.D2372N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV53760164; called by muse, mutect2, varscan2
- ATP2A3 | c.1667C>G p.S556* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | catalogued as COSV59226091; called by muse, mutect2, varscan2
- ATP2B4 | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as COSV100397200; called by muse, mutect2
- ATP7A | c.1710G>C p.V570= | Splice Region (SNP) | VAF 104/261 reads (40%) | catalogued as COSV58450541; called by muse, mutect2, varscan2
- ATP8A2 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.135); catalogued as rs373663072, COSV54965710; called by muse, mutect2, varscan2
- BAHD1 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs375723003, COSV69083916, COSV69084123; called by muse, mutect2, varscan2
- BCO1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as COSV50731296; called by muse, mutect2, varscan2
- BCOR | c.1996A>T p.I666F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV60713384; called by muse, mutect2, varscan2
- BDP1 | c.6358C>T p.Q2120* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100702811, COSV62431267; called by muse, mutect2, varscan2
- BDP1 | c.6796C>G p.Q2266E | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.134); catalogued as COSV62432939; called by muse, mutect2, varscan2
- BEST1 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV56446111; called by muse, mutect2, varscan2
- BIN2 | c.1232C>G p.S411* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99909235; called by muse, mutect2, varscan2
- BNC1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61758411; called by muse, mutect2, varscan2
- BRD4 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV54590521; called by mutect2, varscan2
- BRINP2 | c.2147C>T p.A716V | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV64178972; called by muse, mutect2, varscan2
- BTBD3 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs774418009, COSV54779737, COSV54780472; called by muse, mutect2, varscan2
- C16orf72 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 32/129 reads (25%) | catalogued as COSV59915973; called by muse, mutect2, varscan2
- C20orf194 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99330374; called by muse, varscan2
- C2CD2 | c.1938G>C p.M646I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV61600067; called by muse, mutect2, varscan2
- C2orf88 | c.12G>A p.M4I | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1159113878, COSV61410526; called by muse, mutect2, varscan2
- C5orf34 | c.1479G>C p.K493N | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV60931333; called by muse, mutect2, varscan2
- C6orf15 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52539079, COSV99457339; called by muse, mutect2, varscan2
- C6orf62 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV65290943; called by muse, mutect2, varscan2
- C9orf131 | c.2089G>C p.E697Q | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV56612671; called by muse, mutect2, varscan2
- C9orf16 | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV99476691; called by muse, mutect2
- CABS1 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV56734134; called by muse, mutect2, varscan2
- CACNA1S | c.3556G>C p.D1186H | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62941908; called by muse, mutect2
- CAMK2G | c.637C>G p.P213A | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV59483900; called by muse, mutect2, varscan2
- CARD11 | c.3080G>A p.R1027Q | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.545); catalogued as rs764490474, COSV67796927; called by muse, mutect2, varscan2
- CARNS1 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs751106258, COSV57052797; called by muse, mutect2, varscan2
- CCAR1 | c.3405G>C p.K1135N | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.95); catalogued as COSV56271905; called by muse, mutect2, varscan2
- CCDC136 | c.3235G>T p.E1079* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as rs1311365591, COSV99922289; called by muse, mutect2, varscan2
- CCDC65 | c.610-1G>C p.X204_splice | Splice Site (SNP) | VAF 10/59 reads (17%) | catalogued as COSV56739200, COSV56739912; called by muse, mutect2, varscan2
- CCDC96 | c.1279G>T p.E427* | Nonsense Mutation (SNP) | VAF 26/152 reads (17%) | catalogued as rs779811553, COSV100027721, COSV100027819; called by muse, mutect2, varscan2
- CCNG1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as COSV61652214; called by muse, mutect2, varscan2
- CCT2 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV54740895; called by muse, mutect2, varscan2
- CCT3 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV55290429; called by muse, mutect2, varscan2
- CD109 | c.1726C>G p.L576V | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1044702086, COSV54650770, COSV54653499; called by muse, mutect2, varscan2
- CD163 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs867643659, COSV63135418; called by muse, mutect2, varscan2
- CD274 | c.411C>G p.I137M | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV67501576; called by muse, mutect2, varscan2
- CD40 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV64848069; called by muse, mutect2, varscan2
- CD53 | c.380C>G p.S127* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99602117; called by muse, mutect2, varscan2
- CDH19 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50967650; called by muse, mutect2, varscan2
- CENPJ | c.1897C>G p.H633D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV67883849; called by muse, mutect2, varscan2
- CENPK | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54468966; called by muse, mutect2, varscan2
- CEP162 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.106); catalogued as COSV100002454; called by muse, mutect2
- CEP192 | c.4126G>C p.E1376Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1472527648, COSV100380665, COSV58067929; called by muse, mutect2, varscan2
- CEP192 | c.7031G>A p.S2344N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV58067941; called by mutect2, varscan2
- CFAP43 | c.4497G>C p.Q1499H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV63854103; called by muse, mutect2, varscan2
- CFAP43 | c.2965G>C p.D989H | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV53379742; called by muse, mutect2, varscan2
- CFAP70 | c.3288G>T p.L1096= | Splice Region (SNP) | VAF 13/44 reads (30%) | catalogued as COSV60285351; called by muse, mutect2, varscan2
- CFH | c.1774G>T p.V592L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV66411075, COSV66413787; called by muse, mutect2, varscan2
- CFTR | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs397508632, COSV50075296, COSV99135131, COSV99135516; called by muse, mutect2, varscan2
- CHKA | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV55836756; called by muse, mutect2, varscan2
- CIC | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99359114; called by muse, mutect2
- CIP2A | c.2179C>G p.L727V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55420158; called by muse, mutect2, varscan2
- CKAP4 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100952408; called by muse, mutect2, varscan2
- CLC | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as rs867849565, COSV55686321; called by muse, mutect2, varscan2
- CLCA4 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100991071; called by muse, mutect2, varscan2
- CLEC3A | c.588G>T p.K196N (on ENST00000651443; = p.K187N on NM_005752.6) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV100222092; called by muse, mutect2
- CLIC1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV65383796; called by muse, mutect2, varscan2
- CLIP1 | c.3931C>G p.Q1311E (on ENST00000620786 / NM_001247997.1; = p.Q1300E on NM_002956.2) | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV56805537; called by muse, mutect2, varscan2
- CLIP1 | c.1307+1G>T p.X436_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV56805554, COSV56806046; called by muse, mutect2, varscan2
- CLPB | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99577699; called by muse, varscan2
- CNN1 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.615); catalogued as COSV52956597; called by muse, varscan2
- CNPY2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV56264793; called by muse, mutect2, varscan2
- COA1 | c.391C>T p.P131S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.453); catalogued as COSV56243013; called by muse, mutect2, varscan2
- COG3 | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.541); catalogued as COSV63074099; called by muse, mutect2, varscan2
- COL11A1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs747506988, COSV62190305; called by mutect2, varscan2
- COL1A1 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1435869455, COSV56804765; called by muse, mutect2, varscan2
- COL1A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs968606802, COSV56805074, COSV56807751; called by muse, mutect2, varscan2
- CPA4 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763242315, COSV55982736; called by muse, mutect2, varscan2
- CRHR2 | c.1014C>G p.I338M | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); catalogued as COSV59266896; called by muse, mutect2, varscan2
- CRISP1 | c.241T>A p.Y81N | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV59994592; called by muse, mutect2, varscan2
- CRISP3 | c.96G>A p.M32I (on ENST00000371159 / NM_001368123.1; = p.M14I on NM_006061.4) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as rs754601699, COSV53821976; called by muse, mutect2, varscan2
- CRY2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs369560580, COSV101314625; called by muse, mutect2, varscan2
- CRYBA4 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV100697765, COSV100697828; called by muse, mutect2, varscan2
- CTNNB1 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as COSV62697581, COSV62709891; called by muse, mutect2, varscan2
- CUX1 | c.2433A>T p.K811N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99470742; called by muse, mutect2, varscan2
- CXADR | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV53030118; called by muse, mutect2, varscan2
- CYP4V2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV66506877; called by muse, mutect2, varscan2
- DALRD3 | c.667G>T p.E223* (on ENST00000341949 / NM_001009996.3; = p.E56* on NM_018114.5) | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100482760; called by muse, mutect2, varscan2
- DCAF4L2 | c.1126C>T p.R376* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV60481489; called by muse, mutect2, varscan2
- DCHS1 | c.4726G>A p.E1576K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100201611; called by muse, mutect2
- DCTN1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as COSV100720877; called by muse, mutect2, varscan2
- DDX1 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as COSV51841534; called by muse, mutect2, varscan2
- DDX20 | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs768178338, COSV63831411; called by muse, mutect2, varscan2
- DDX20 | c.1638G>A p.M546I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV63780371; called by muse, mutect2, varscan2
- DDX3X | c.1168-1G>C p.X390_splice (on ENST00000399959; = p.X391_splice on NM_001356.5) | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as COSV67864099; called by muse, mutect2, varscan2
- DDX3X | c.1943G>A p.G648E (on ENST00000399959; = p.G649E on NM_001356.5) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV67864100; called by muse, mutect2, varscan2
- DHRS9 | c.459G>T p.K153N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59140874; called by muse, varscan2
- DIDO1 | c.5745G>C p.Q1915H | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as COSV56629336; called by muse, mutect2, varscan2
- DMTF1 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.879); catalogued as COSV57538967; called by muse, mutect2, varscan2
- DNAH5 | c.13735C>G p.P4579A | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV54210768, COSV54240499; called by muse, mutect2, varscan2
- DNAH5 | c.13207G>C p.V4403L | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV54240507; called by muse, mutect2, varscan2
- DNAH9 | c.4791G>C p.K1597N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52363642; called by muse, mutect2, varscan2
- DNAJC10 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV51142691; called by muse, mutect2, varscan2
- DNMT3B | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99140538; called by muse, mutect2, varscan2
- DNTTIP2 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63284441; called by muse, mutect2
- DSG2 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.23); catalogued as COSV55201126; called by muse, mutect2, varscan2
- DUSP1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs201749251, COSV53320638; called by muse, mutect2, varscan2
- DYNC1H1 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV64139744; called by muse, mutect2, varscan2
- EEF2KMT | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV69863596; called by muse, mutect2
- EIF2AK2 | c.1475C>G p.S492* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99240374; called by muse, mutect2, varscan2
- EIF2AK4 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55471638; called by muse, mutect2, varscan2
- EIF3E | c.454T>C p.Y152H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV55204516; called by muse, mutect2, varscan2
- EMILIN1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.465); catalogued as rs1558432695; called by muse, mutect2
- EML1 | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99214622; called by muse, mutect2, varscan2
- ENKUR | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV100481999, COSV58634116; called by muse, mutect2, varscan2
- EPHB2 | c.515G>C p.S172T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV65864430; called by muse, mutect2, varscan2
- EPHB4 | c.2768G>C p.R923T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100639421; called by muse, mutect2
- EQTN | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs868670673, COSV66218272; called by muse, mutect2, varscan2
- EZH1 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.274); catalogued as COSV70550168; called by muse, mutect2, varscan2
- F5 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV63126216; called by muse, mutect2, varscan2
- F8 | c.2356G>C p.E786Q | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as COSV64273809, COSV64276478; called by muse, mutect2, varscan2
- FAM120B | c.2450C>T p.S817F | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV53006480; called by muse, mutect2, varscan2
- FAT4 | c.9763C>T p.Q3255* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100627472, COSV58698755; called by muse, mutect2, varscan2
- FATE1 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV64848992; called by muse, mutect2, varscan2
- FBXO34 | c.1943G>T p.R648L | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV58254210, COSV58255842; called by muse, mutect2, varscan2
- FBXO38 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV57029716; called by muse, mutect2, varscan2
- FER | c.1192C>G p.P398A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV55298586; called by muse, mutect2, varscan2
- FILIP1L | c.3364C>G p.R1122G (on ENST00000354552 / NM_182909.3; = p.R882G on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58772682; called by muse, mutect2, varscan2
- FLNB | c.1222G>T p.D408Y | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55887663; called by muse, mutect2, varscan2
- FMN2 | c.4115T>C p.M1372T | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60429420, COSV60442407; called by muse, mutect2, varscan2
- FNDC1 | c.2108C>T p.S703L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV51930106; called by muse, varscan2
- FNDC1 | c.2180C>G p.S727C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV51932202, COSV99795160; called by muse, varscan2
- FRMD5 | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV68723963; called by muse, mutect2, varscan2
- FRS3 | c.320G>A p.C107Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.959); catalogued as rs764812166, COSV52485256; called by muse, mutect2, varscan2
- FZD8 | c.1608C>A p.F536L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65968175; called by muse, mutect2, varscan2
- GABRB1 | c.1317G>C p.K439N | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV54973859, COSV54992372; called by muse, mutect2, varscan2
- GAPT | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV59247208; called by muse, mutect2, varscan2
- GCC2 | c.3327G>C p.Q1109H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs1173033029, COSV59178442; called by muse, mutect2, varscan2
- GCLC | c.934G>A p.E312K (on ENST00000643939; = p.E310K on NM_001498.4) | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV57596803; called by muse, mutect2, varscan2
- GCNT4 | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV59281343; called by muse, mutect2, varscan2
- GDF2 | c.847G>A p.V283M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs138904328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GEMIN5 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53562881; called by muse, mutect2, varscan2
- GFPT2 | c.1955T>C p.I652T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53810718; called by muse, mutect2, varscan2
- GGH | c.926C>G p.S309C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV52651253; called by muse, mutect2
- GINM1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100805289; called by muse, mutect2, varscan2
- GJB7 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV51530840; called by muse, mutect2, varscan2
- GLCE | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV55947184; called by muse, mutect2, varscan2
- GLRX2 | c.345G>A p.M115I (on ENST00000367439 / NM_197962.3; = p.M116I on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.901); catalogued as COSV66472155; called by muse, mutect2, varscan2
- GNRHR | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV56934306; called by muse, mutect2, varscan2
- GOT1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV65147637; called by muse, mutect2, varscan2
- GPCPD1 | c.386G>A p.C129Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV66831388; called by muse, mutect2, varscan2
- GPS2 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV59751966; called by muse, mutect2, varscan2
- GPS2 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV59751976; called by muse, mutect2, varscan2
- GRAMD1A | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV100526014; called by muse, mutect2
- GRK3 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60794433, COSV60798639; called by muse, mutect2, varscan2
- GRM1 | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV51211001; called by muse, mutect2, varscan2
- GSTCD | c.1356+1G>A p.X452_splice (on ENST00000360505 / NM_001031720.3; = p.X365_splice on NM_024751.3) | Splice Site (SNP) | VAF 26/78 reads (33%) | catalogued as COSV64734601; called by muse, mutect2, varscan2
- H2BC14 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.045); catalogued as rs141452609, COSV60798695; called by muse, mutect2, varscan2
- HCN1 | c.2567T>A p.V856D | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as COSV57525659; called by muse, mutect2
- HECTD2 | c.2262G>C p.K754N | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV53223158; called by muse, mutect2, varscan2
- HGF | c.2052G>A p.M684I | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55953559, COSV99736713; called by muse, mutect2, varscan2
- HIF1AN | c.885C>G p.F295L | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV54501321; called by muse, mutect2, varscan2
- HIVEP3 | c.5107G>C p.A1703P | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.694); catalogued as COSV56019524; called by muse, mutect2, varscan2
- HMG20A | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100287676; called by muse, mutect2, varscan2
- HMG20B | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs910167171, COSV53572237; called by muse, mutect2, varscan2
- HMGXB4 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53334749; called by muse, mutect2, varscan2
- HNF1A | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.844); catalogued as COSV99982230; called by muse, mutect2
- HOMEZ | c.1335G>C p.L445F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.982); catalogued as rs1261557770, COSV100664053, COSV62538061; called by muse, mutect2
- HPS4 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV61104493; called by muse, mutect2, varscan2
- HSD17B4 | c.1009C>T p.H337Y (on ENST00000414835 / NM_001199291.3; = p.H312Y on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.259); catalogued as rs974081530, COSV56337730; called by muse, mutect2, varscan2
- HSDL1 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs761090490, COSV54741767, COSV54742208; called by muse, mutect2, varscan2
- HSF5 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60415516, COSV60418195; called by muse, mutect2, varscan2
- HSPA5 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.312); catalogued as COSV52337091; called by muse, mutect2, varscan2
- HSPBAP1 | c.213G>C p.Q71H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.587); catalogued as COSV60243096; called by muse, mutect2, varscan2
- HTR3C | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV59176682; called by muse, mutect2
- HUWE1 | c.5923G>C p.E1975Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.146); catalogued as COSV53356428; called by muse, mutect2, varscan2
- HYAL4 | c.858G>C p.M286I | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV56139530; called by muse, mutect2, varscan2
- IFIH1 | c.1600G>C p.E534Q | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.323); catalogued as COSV55128594; called by muse, mutect2, varscan2
- IL16 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57266412; called by muse, mutect2, varscan2
- IL18BP | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV52621944; called by muse, mutect2, varscan2
- IMPG2 | c.3619G>C p.E1207Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV51982508; called by muse, mutect2, varscan2
- ITGA4 | c.557-1G>C p.X186_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52002318, COSV99275835; called by muse, mutect2, varscan2
- ITGA4 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52002332; called by muse, mutect2, varscan2
- ITGAM | c.1670A>T p.H557L (on ENST00000648685 / NM_001145808.2; = p.H556L on NM_000632.4) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV54939899; called by muse, mutect2, varscan2
- ITGB8 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as rs1272692791, COSV56011708; called by muse, mutect2, varscan2
- JHY | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as COSV56220785; called by muse, mutect2, varscan2
- KBTBD2 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV58363939; called by muse, mutect2, varscan2
- KCNB2 | c.2275G>A p.E759K | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.856); catalogued as rs768925064, COSV73050505; called by muse, mutect2, varscan2
- KHDRBS2 | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | catalogued as COSV99831699; called by muse, mutect2, varscan2
- KIAA1109 | c.8676C>G p.F2892L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52684308; called by muse, mutect2, varscan2
- KIAA1109 | c.10498G>C p.D3500H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52684328; called by muse, mutect2, varscan2
- KIAA1109 | c.10862C>G p.S3621C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.219); catalogued as COSV52684346; called by muse, mutect2, varscan2
- KIAA2026 | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs763265858, COSV67356606; called by muse, mutect2, varscan2
- KIF16B | c.1969A>G p.S657G | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV61710451; called by muse, mutect2, varscan2
- KIF26A | c.1954C>T p.P652S | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV59468666; called by muse, mutect2, varscan2
- KIF26A | c.1955C>A p.P652H | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1434280961, COSV59465710, COSV59468674; called by muse, mutect2, varscan2
- KLHL11 | c.1290G>C p.L430F | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT tolerated (0.4); PolyPhen benign (0.24); catalogued as COSV59862611; called by muse, mutect2, varscan2
- KLHL23 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV55868564; called by muse, mutect2, varscan2
- KLHL35 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1465258430, COSV66219522; called by muse, mutect2, varscan2
- KMT2C | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 32/340 reads (9%) | catalogued as COSV100068483, COSV51421061, COSV51457733; called by muse, varscan2
- KMT2C | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 45/128 reads (35%) | catalogued as COSV51509345, COSV51518404; called by muse, mutect2, varscan2
- KMT2D | c.16384G>C p.D5462H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM141321, COSV56442420; called by muse, mutect2
- KMT2D | c.14946G>A p.W4982* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as CM114914, COSV56485392, COSV99978363; called by muse, mutect2, varscan2
- KMT2D | c.14734G>A p.E4912K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.646); catalogued as rs1445664162, COSV56466357; called by muse, mutect2, varscan2
- KRT16 | c.504C>G p.F168L | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV56968979; called by muse, mutect2, varscan2
- KRT222 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as COSV67498703; called by muse, mutect2, varscan2
- KRT24 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 58/108 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV52880160; called by muse, varscan2
- KRT40 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1477607974, COSV66696575, COSV66696650; called by muse, mutect2, varscan2
- KTI12 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100860204, COSV65405981; called by muse, mutect2, varscan2
- KTI12 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.157); catalogued as rs1205801211, COSV65406125; called by mutect2, varscan2
- LAD1 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV66212970; called by muse, mutect2, varscan2
- LAMA1 | c.5668G>C p.E1890Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.094); catalogued as COSV67541135; called by muse, mutect2
- LAMC2 | c.1594G>C p.D532H | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV51457987; called by muse, mutect2, varscan2
- LDB1 | c.1045G>C p.G349R (on ENST00000425280 / NM_001321612.2; = p.G315R on NM_003893.5) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63288986, COSV63289645; called by muse, mutect2, varscan2
- LGI1 | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65057552; called by muse, mutect2, varscan2
- LGI3 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); catalogued as rs752250633, COSV60443890; called by muse, mutect2, varscan2
- LILRB3 | c.1805C>T p.S602F (on ENST00000346401; = p.S590F on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54441331; called by muse, mutect2, varscan2
- LIPF | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53285250; called by muse, mutect2, varscan2
- LOXL2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs780406585, COSV66692590; called by muse, mutect2, varscan2
- LRFN2 | c.1448C>G p.S483* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100599189; called by muse, mutect2, varscan2
- LRGUK | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs994266528, COSV53636242, COSV53640942; called by muse, mutect2, varscan2
- LRP6 | c.2122G>C p.E708Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV53791157; called by muse, mutect2, varscan2
- LRRC14 | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52881070; called by muse, varscan2
- LRRC14 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52881085; called by muse, varscan2
- LRRC14 | c.954C>G p.F318L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV52881103; called by muse, varscan2
- LRRC23 | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs1226922378, COSV50391293, COSV50392466; called by muse, mutect2, varscan2
- LRRK2 | c.5162C>T p.S1721L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as rs1278113661, COSV54162354; called by muse, mutect2, varscan2
- LRRK2 | c.6586G>C p.D2196H | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV100109450; called by muse, mutect2
- LTBR | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99965203; called by muse, mutect2, varscan2
- LYST | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as COSV101088476; called by muse, mutect2, varscan2
- LYZL1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV100973677, COSV64966640; called by muse, mutect2
- MAN2C1 | c.1969A>C p.M657L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99145252; called by muse, mutect2
- MAPK3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53775344; called by muse, mutect2, varscan2
- MAPKBP1 | c.4171G>T p.E1391* (on ENST00000456763 / NM_001128608.2; = p.E1385* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as COSV52963710, COSV99529030; called by muse, mutect2, varscan2
- MAPKBP1 | c.4375G>A p.D1459N (on ENST00000456763 / NM_001128608.2; = p.D1453N on NM_014994.3) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1190393982, COSV52964784; called by muse, mutect2, varscan2
- MARF1 | c.1157G>C p.R386T | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60026541; called by muse, mutect2, varscan2
- MBL2 | c.129C>G p.I43M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV100906266, COSV64759011; called by muse, varscan2
- MCHR2 | c.753G>C p.K251N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV56006144; called by muse, mutect2, varscan2
- MCM6 | c.2232G>C p.K744N | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.341); catalogued as COSV51468060; called by muse, mutect2, varscan2
- MCRS1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.956); catalogued as COSV59460674; called by muse, mutect2, varscan2
- MEPE | c.443G>C p.R148T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); catalogued as COSV63073529; called by muse, mutect2, varscan2
- MIS18BP1 | c.3228C>G p.I1076M | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV60372216; called by muse, mutect2, varscan2
- MKI67 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV64072842, COSV64075659; called by muse, mutect2, varscan2
- MNX1 | c.939G>T p.Q313H | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as COSV53318726; called by muse, mutect2, varscan2
- MRC2 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV57642379; called by muse, mutect2, varscan2
- MRPS34 | c.369G>C p.K123N | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV51600498; called by muse, mutect2, varscan2
- MTBP | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.242); catalogued as COSV59964743; called by muse, mutect2, varscan2
- MTDH | c.944G>C p.R315T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60345535; called by muse, mutect2, varscan2
- MTERF2 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53528131; called by muse, mutect2, varscan2
- MTRES1 | c.189C>G p.F63L | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV60968464; called by muse, mutect2, varscan2
- MTREX | c.3093G>C p.K1031N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV53306763; called by muse, mutect2, varscan2
- MTTP | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as COSV55507350, COSV55508194; called by muse, mutect2, varscan2
- MVB12A | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV57679339; called by muse, mutect2, varscan2
- MYF5 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as rs893795100, COSV57354577; called by muse, mutect2, varscan2
- MYH7 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1555338255, COSV62521682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK3 | c.1399C>G p.P467A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV67365613; called by muse, mutect2, varscan2
- MYO1A | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55656004; called by muse, mutect2, varscan2
- MYOM3 | c.3926C>G p.S1309* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV100141578; called by muse, mutect2, varscan2
- NAAA | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1300111406, COSV54433140; called by muse, mutect2, varscan2
- NAALADL2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV70795157; called by muse, mutect2, varscan2
- NBPF1 | c.670C>G p.H224D | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.702); catalogued as COSV101236225; called by muse, mutect2
- NCKAP5 | c.1686G>C p.E562D | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV58461541; called by muse, mutect2, varscan2
- NCOA6 | c.6118C>T p.R2040* | Nonsense Mutation (SNP) | VAF 19/95 reads (20%) | catalogued as rs1407547711, COSV100749925; called by muse, mutect2, varscan2
- NDC1 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 8/53 reads (15%) | catalogued as COSV99323345; called by muse, mutect2, varscan2
- NDST4 | c.1418G>C p.R473P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047405343, COSV52129060; called by muse, mutect2, varscan2
- NECAP1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV60250071; called by muse, mutect2, varscan2
- NLRX1 | c.1788G>C p.Q596H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52706938; called by muse, mutect2, varscan2
- NME5 | c.594C>G p.N198K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1160767525, COSV54523499; called by muse, mutect2, varscan2
- NOTCH3 | c.5063C>G p.S1688C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.345); catalogued as COSV54642250; called by muse, mutect2, varscan2
- NPAT | c.1907C>G p.S636C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV53719857; called by muse, mutect2, varscan2
- NPHP3 | c.3582C>G p.D1194E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV58631992; called by muse, mutect2, varscan2
- NPTX1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 53/81 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1053415479, COSV60774762, COSV60775812; called by muse, mutect2, varscan2
- NRF1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV56214648; called by muse, mutect2, varscan2
- NSD3 | c.3926G>A p.R1309K | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1225975674, COSV57668163, COSV57672166; called by muse, mutect2
- NSF | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV56574533; called by muse, mutect2, varscan2
- NSUN2 | c.1786G>T p.E596* | Nonsense Mutation (SNP) | VAF 29/83 reads (35%) | catalogued as COSV99243014; called by muse, mutect2, varscan2
- NSUN6 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV66034319; called by muse, mutect2, varscan2
- NUP43 | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV61190706; called by muse, mutect2, varscan2
- NUP62 | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV61312238, COSV61312943; called by muse, mutect2, varscan2
- OBSCN | c.10150G>A p.E3384K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV52802636; called by muse, mutect2, varscan2
- OLAH | c.211C>A p.L71I (on ENST00000378228 / NM_001039702.3; = p.L124I on NM_018324.3) | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV65492709; called by muse, mutect2, varscan2
- OLFML2B | c.1853C>G p.S618* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99668116; called by muse, mutect2, varscan2
- OPRPN | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV68193871; called by muse, mutect2, varscan2
- OR10P1 | c.585G>C p.R195S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.096); catalogued as rs761605993, COSV59007691, COSV59007825; called by muse, mutect2, varscan2
- OR1S2 | c.915G>C p.L305F | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV56919966, COSV56920696; called by muse, mutect2, varscan2
- OR4S1 | c.512A>T p.E171V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV60679535; called by muse, mutect2, varscan2
- OR5H14 | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as COSV71194273; called by muse, mutect2, varscan2
- OR8D4 | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.003); catalogued as COSV58429975, COSV58430359; called by muse, mutect2
- OSGEP | c.894G>C p.M298I | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52833234; called by muse, mutect2, varscan2
- PACC1 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV54788858; called by muse, mutect2, varscan2
- PARD3 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as rs1457783014, COSV100400428; called by muse, mutect2, varscan2
- PARVB | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.083); catalogued as COSV58689427; called by muse, mutect2, varscan2
- PATJ | c.4576G>C p.E1526Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV57167361; called by muse, mutect2, varscan2
- PBX1 | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.132); catalogued as COSV63346204; called by muse, mutect2, varscan2
- PCDH1 | c.2109C>G p.I703M | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54617126; called by muse, mutect2, varscan2
- PCDH17 | c.3280G>T p.D1094Y | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.497); catalogued as COSV64973557, COSV64976754; called by muse, mutect2, varscan2
- PCDH19 | c.3386T>A p.L1129Q (on ENST00000373034 / NM_001184880.2; = p.L1081Q on NM_020766.3) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV55267833; called by muse, mutect2, varscan2
- PCDHB4 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV52024895; called by muse, mutect2, varscan2
- PDE10A | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.985); catalogued as COSV63091381, COSV63102047; called by muse, mutect2, varscan2
- PDE3A | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62969798; called by muse, mutect2, varscan2
- PDIA5 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as COSV60250768; called by muse, mutect2, varscan2
- PDXDC1 | c.1897C>G p.L633V | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as rs535483075, COSV55075139; called by muse, mutect2, varscan2
- PDZD2 | c.1831C>A p.Q611K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.468); catalogued as COSV56866127; called by muse, mutect2
- PDZRN3 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1321104627, COSV55208993; called by muse, mutect2, varscan2
- PEAK1 | c.2989C>G p.Q997E | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV56931205; called by muse, mutect2, varscan2
- PHF1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as rs376639282; called by muse, mutect2, varscan2
- PHF3 | c.485C>G p.S162C | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV50328364, COSV50342219; called by muse, mutect2, varscan2
- PHKB | c.3035G>C p.R1012T | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54528450; called by muse, mutect2, varscan2
- PIDD1 | c.2521G>A p.E841K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.506); catalogued as rs1251999632, COSV57193289, COSV57194258; called by muse, mutect2, varscan2
- PIEZO2 | c.7545G>C p.Q2515H | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV53288441, COSV53292061; called by muse, mutect2, varscan2
- PIFO | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63863825; called by muse, mutect2, varscan2
- PIK3R1 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57134906; called by muse, mutect2, varscan2
- PKN2 | c.1517G>C p.R506T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60133311; called by muse, mutect2, varscan2
- PKP4 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs1030891444, COSV67678414; called by muse, mutect2, varscan2
- PLA2G3 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV53209404; called by muse, mutect2, varscan2
- PLA2R1 | c.849G>C p.M283I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1400316392, COSV99322362, COSV99322886; called by muse, varscan2
- PLCB1 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62060368; called by muse, mutect2, varscan2
- PLN | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV62645924, COSV62646323; called by muse, mutect2, varscan2
- PLRG1 | c.953G>C p.R318T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57424251; called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1446C>G p.F482L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV100544078, COSV57963690; called by muse, mutect2
- POLK | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV54037597, COSV99605890; called by muse, mutect2, varscan2
- POLR1B | c.2791G>C p.E931Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54501234; called by muse, mutect2, varscan2
- POTEF | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs745593222, COSV100665337, COSV62541770; called by mutect2, varscan2
- POU2F1 | c.1011G>C p.K337N (on ENST00000541643 / NM_001365848.1; = p.K360N on NM_002697.4) | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV54821361; called by muse, mutect2, varscan2
- POU2F1 | c.1893G>C p.M631I (on ENST00000541643 / NM_001365848.1; = p.M654I on NM_002697.4) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV54821386; called by muse, mutect2, varscan2
- PPFIA4 | c.2746G>A p.E916K (on ENST00000447715; = p.E917K on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV55318836; called by muse, mutect2, varscan2
- PPP1R21 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs370271261; called by muse, mutect2, varscan2
- PRAMEF18 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 44/435 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs780348075; called by muse, mutect2, varscan2
- PRDM1 | c.1961C>G p.S654C | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64845166, COSV64846106; called by muse, mutect2, varscan2
- PRDM15 | c.2709G>C p.K903N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV54156354; called by muse, mutect2, varscan2
- PREX2 | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs866534903, COSV55770593; called by muse, mutect2, varscan2
- PRKCE | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV60324757; called by muse, mutect2, varscan2
- PRKCI | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV55520991, COSV99855743; called by muse, mutect2, varscan2
- PRKN | c.1151C>A p.S384* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100627805; called by muse, mutect2
- PRMT7 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV59834490; called by muse, mutect2, varscan2
- PRPF6 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV53874922; called by muse, mutect2, varscan2
- PRSS36 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs60815794; called by muse, mutect2, varscan2
- PRUNE2 | c.668G>C p.S223T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.843); catalogued as rs755483963, COSV65028649; called by mutect2, varscan2
- PSPH | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV51912013; called by muse, mutect2, varscan2
- PTPRB | c.3598G>A p.D1200N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54247869; called by muse, mutect2, varscan2
- PTPRC | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV61410693, COSV61416967; called by muse, mutect2, varscan2
- PTPRM | c.1319C>G p.S440* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100155511, COSV59853783; called by muse, mutect2, varscan2
- PWWP2A | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100193726, COSV100193765; called by muse, mutect2
- PXDNL | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100682073; called by muse, mutect2
- PXDNL | c.1194T>A p.C398* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as COSV100682074; called by muse, mutect2
- PYCR3 | c.745G>C p.E249Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1168469742, COSV55306286, COSV55306469, COSV55308125; called by muse, mutect2, varscan2
- QRICH2 | c.3398G>A p.R1133K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53155676; called by muse, mutect2, varscan2
- QTRT2 | c.832C>G p.Q278E | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV55560965; called by muse, mutect2, varscan2
- RAB21 | c.168C>G p.F56L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.372); catalogued as COSV54229507; called by muse, varscan2
- RAB3GAP2 | c.3573C>G p.F1191L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV62785809; called by muse, mutect2, varscan2
- RABGAP1L | c.578C>G p.S193C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV52311687; called by muse, mutect2, varscan2
- RAI14 | c.2443G>C p.E815Q | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54299429; called by muse, mutect2
- RALGAPA2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99173208; called by muse, mutect2, varscan2
- RANBP10 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.098); catalogued as COSV58159795; called by muse, mutect2, varscan2
- RAPGEF6 | c.3686C>T p.S1229F | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV57240611, COSV57251209; called by muse, mutect2, varscan2
- RBAK | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs777136789, COSV62332061; called by muse, mutect2, varscan2
- RBM43 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV58879457; called by muse, mutect2, varscan2
- RBP2 | c.73G>T p.D25Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV51674384; called by muse, mutect2, varscan2
- RECQL5 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs202116343; called by muse, mutect2, varscan2
- REG1A | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52069661, COSV52070635; called by muse, mutect2, varscan2
- RFX3 | c.732-1G>C p.X244_splice | Splice Site (SNP) | VAF 15/36 reads (42%) | catalogued as COSV56521012; called by muse, mutect2, varscan2
- RIF1 | c.4865A>G p.Q1622R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1160420031, COSV54620908; called by muse, mutect2, varscan2
- RIOX2 | c.1159C>G p.Q387E (on ENST00000333396 / NM_001042533.2; = p.Q386E on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99476670; called by muse, mutect2
- RIPK2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99609731; called by muse, mutect2
- RIPK2 | c.692-1G>T p.X231_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as COSV55134243; called by muse, mutect2, varscan2
- RLF | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.473); catalogued as COSV65650647; called by muse, mutect2, varscan2
- RNF40 | c.1339C>T p.Q447* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100221932; called by muse, mutect2, varscan2
- ROS1 | c.6977C>T p.S2326F | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as rs1430294646, COSV63858782; called by muse, mutect2, varscan2
- RPGRIP1L | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 61/162 reads (38%) | catalogued as rs547189939, COSV100045947; called by muse, mutect2, varscan2
- RPLP0 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs761578930, COSV56103883, COSV99935331; called by muse, mutect2, varscan2
- RSPH3 | c.1650G>A p.M550I (on ENST00000252655; = p.M408I on NM_031924.8) | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1562557487, COSV51923850; called by muse, mutect2, varscan2
- SCAF11 | c.4173C>G p.I1391M | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65478010; called by muse, mutect2, varscan2
- SCN8A | c.5410G>C p.E1804Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV61987725; called by muse, mutect2, varscan2
- SDHA | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as COSV53771350; called by muse, mutect2, varscan2
- SDK1 | c.3559G>T p.E1187* | Nonsense Mutation (SNP) | VAF 46/115 reads (40%) | catalogued as COSV101268860; called by muse, mutect2, varscan2
- SDR9C7 | c.189G>T p.Q63H | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV53290122; called by muse, mutect2, varscan2
- SEC22C | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52566343; called by muse, mutect2, varscan2
- SEC24B | c.3541G>C p.E1181Q | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV54495125, COSV54496505, COSV54503436; called by muse, mutect2, varscan2
- SEC24C | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866634007, COSV59543604; called by muse, mutect2, varscan2
- SEC31B | c.1075C>G p.L359V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV64825013; called by muse, mutect2, varscan2
- SENP7 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs763017220, COSV58615391; called by muse, mutect2
- SERAC1 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.338); catalogued as COSV65597392; called by muse, mutect2, varscan2
- SERPIND1 | c.1101G>C p.K367N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV53140029; called by muse, mutect2, varscan2
- SET | c.684C>G p.N228K (on ENST00000372692 / NM_001374326.1; = p.N215K on NM_003011.4) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59003555; called by muse, mutect2, varscan2
- SETDB1 | c.2698G>T p.E900* | Nonsense Mutation (SNP) | VAF 18/42 reads (43%) | catalogued as COSV54980426; called by muse, mutect2, varscan2
- SEZ6L2 | c.1330G>C p.E444Q (on ENST00000308713 / NM_001114099.3; = p.E374Q on NM_012410.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV58101585; called by muse, mutect2, varscan2
- SFXN4 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57460177; called by muse, mutect2, varscan2
- SFXN4 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.127); catalogued as COSV57460590; called by muse, mutect2
- SIAH2 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57262617; called by muse, mutect2, varscan2
- SLC6A7 | c.1438C>G p.Q480E | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV57939667; called by muse, mutect2, varscan2
- SLC8A1 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.414); catalogued as COSV60478460; called by muse, mutect2, varscan2
- SLCO1B1 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.535); catalogued as COSV57014250; called by muse, varscan2
- SLX4 | c.3703C>T p.P1235S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.116); catalogued as COSV53563371, COSV53566424; called by muse, mutect2, varscan2
- SMARCAD1 | c.1334G>A p.C445Y | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV62775505; called by muse, mutect2, varscan2
- SMCR8 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1001067533, COSV58179538; called by muse, mutect2, varscan2
- SMCR8 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV58179541; called by muse, mutect2, varscan2
- SMO | c.2361C>G p.F787L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV50835322, COSV50842869; called by muse, varscan2
- SNAP47 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1264544698, COSV59918186, COSV59919152; called by muse, mutect2, varscan2
- SNED1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.14); catalogued as rs1308442233, COSV100122308; called by muse, mutect2, varscan2
- SNX19 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.086); catalogued as rs1243275942, COSV56287386; called by muse, mutect2, varscan2
- SPEF2 | c.5197G>A p.E1733K | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.75); PolyPhen benign (0.068); catalogued as COSV57430935; called by muse, mutect2, varscan2
- SPIDR | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99854405, COSV99855991; called by muse, mutect2, varscan2
- ST18 | c.2830G>A p.E944K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52500608, COSV52502438; called by muse, mutect2, varscan2
- STAP2 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV74075481; called by muse, mutect2, varscan2
- STAT1 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.322); catalogued as rs1487182042, COSV63115126, COSV63116455, COSV63116987; called by muse, mutect2, varscan2
- STX2 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99892479; called by muse, mutect2
- SYCP1 | c.2525C>T p.S842F | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.671); catalogued as COSV65699687; called by muse, mutect2, varscan2
- SYNE1 | c.14620G>A p.E4874K (on ENST00000367255 / NM_182961.4; = p.E4803K on NM_033071.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs147947110; called by muse, mutect2, varscan2
- SYNE1 | c.12805G>C p.E4269Q (on ENST00000367255 / NM_182961.4; = p.E4198Q on NM_033071.3) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV55043634; called by muse, mutect2, varscan2
- SZT2 | c.8635C>T p.R2879C (on ENST00000634258 / NM_001365999.1; = p.R2822C on NM_015284.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs769509671, COSV65172089; called by muse, varscan2
- TAAR1 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 55/183 reads (30%) | catalogued as COSV99257488; called by muse, mutect2, varscan2
- TAF1A | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1435184256, COSV100601068, COSV61919256; called by muse, mutect2, varscan2
- TAGLN2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.204); catalogued as COSV57422934; called by muse, mutect2, varscan2
- TANC2 | c.5548G>C p.D1850H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV67338112; called by muse, mutect2, varscan2
- TASOR2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746590270, COSV60167193; called by muse, mutect2, varscan2
- TBX1 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV60354757, COSV60355092; called by muse, mutect2, varscan2
- TCF20 | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100166344, COSV100166556; called by muse, mutect2, varscan2
- TDRD6 | c.6110C>G p.S2037* | Nonsense Mutation (SNP) | VAF 27/104 reads (26%) | catalogued as rs747967687, COSV100287256; called by muse, mutect2, varscan2
- TECTA | c.6371C>G p.S2124C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.173); catalogued as COSV50755293; called by muse, mutect2, varscan2
- TERF2 | c.1515G>C p.Q505H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV54748339; called by muse, mutect2, varscan2
- TESK1 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.204); catalogued as rs750193760, COSV52411871; called by muse, mutect2, varscan2
- TESK2 | c.1276C>G p.L426V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV59155366; called by muse, mutect2, varscan2
- THAP6 | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61162551; called by muse, mutect2, varscan2
- TLR7 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV66124924; called by muse, mutect2, varscan2
- TMEM8B | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as COSV65075601, COSV65077348; called by muse, mutect2, varscan2
- TMOD1 | c.871-1G>C p.X291_splice | Splice Site (SNP) | VAF 15/24 reads (63%) | catalogued as COSV99403752; called by muse, mutect2, varscan2
- TMUB1 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 41/153 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.584); catalogued as rs1347793783, COSV52541269; called by muse, mutect2, varscan2
- TNFAIP3 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as rs753319492, COSV52798961, COSV52800830; called by muse, mutect2, varscan2
- TNR | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV54901347; called by muse, mutect2, varscan2
- TNS1 | c.69C>G p.I23M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50691401, COSV50732382; called by muse, mutect2, varscan2
- TNS4 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.182); catalogued as COSV54185970; called by muse, mutect2, varscan2
- TOB2 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59501418; called by muse, mutect2, varscan2
- TOGARAM2 | c.1457C>G p.S486W | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65422872, COSV65423886; called by muse, mutect2, varscan2
- TONSL | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1554879344, COSV68047635; called by muse, mutect2
- TOP1MT | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs771915752, COSV61318996; called by muse, mutect2, varscan2
- TOPORS | c.1886C>A p.S629Y | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1405473340, COSV62117625; called by muse, mutect2, varscan2
- TP53 | c.420del p.C141Afs*29 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | catalogued as COSV52700425; called by mutect2, pindel, varscan2
- TPO | c.494G>C p.R165T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV61100171, COSV61106642; called by muse, mutect2, varscan2
- TPP2 | c.3016G>C p.D1006H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); catalogued as COSV65753888; called by muse, mutect2, varscan2
- TRABD | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV57713693; called by muse, mutect2, varscan2
- TRIM29 | c.906C>G p.F302L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.294); catalogued as COSV100531536; called by muse, mutect2
- TRIM69 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV57803890, COSV57804650; called by mutect2, varscan2
- TRIP12 | c.2078-1G>C p.X693_splice | Splice Site (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52263327, COSV52268873; called by muse, mutect2, varscan2
- TRPC4 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as COSV58998250, COSV59008794; called by muse, mutect2, varscan2
- TRPM1 | c.4279G>A p.E1427K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV56638548; called by muse, mutect2, varscan2
- TSNARE1 | c.1397C>G p.S466W | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100209965; called by muse, mutect2
- TTC23L | c.94C>A p.H32N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.082); catalogued as COSV101551103, COSV72205897; called by muse, mutect2
- TTC39C | c.823C>G p.L275V (on ENST00000317571 / NM_001135993.2; = p.L214V on NM_153211.4) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58219385; called by muse, mutect2, varscan2
- TTN | c.93130G>A p.E31044K (on ENST00000591111; = p.E23620K on NM_003319.4) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | PolyPhen probably damaging (0.994); catalogued as COSV60209904, COSV60258195; called by muse, mutect2, varscan2
- TTN | c.81306G>C p.Q27102H (on ENST00000591111; = p.Q19678H on NM_003319.4) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | PolyPhen benign (0.015); catalogued as rs1406219496, COSV60209955; called by muse, mutect2, varscan2
- TTN | c.67543G>A p.D22515N (on ENST00000591111; = p.D15091N on NM_003319.4) | Missense Mutation (SNP) | VAF 58/169 reads (34%) | PolyPhen benign (0.098); catalogued as COSV60191821, COSV60210010; called by muse, mutect2, varscan2
- TTN | c.57458G>C p.R19153T (on ENST00000591111; = p.R11729T on NM_003319.4) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | PolyPhen probably damaging (0.996); catalogued as rs765092290, COSV60210060; called by muse, mutect2, varscan2
- TTN | c.50958G>C p.K16986N (on ENST00000591111; = p.K9562N on NM_003319.4) | Missense Mutation (SNP) | VAF 37/91 reads (41%) | PolyPhen benign (0.023); catalogued as COSV100634129, COSV60210121; called by muse, mutect2, varscan2
- TTN | c.49099G>C p.E16367Q (on ENST00000591111; = p.E8943Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | PolyPhen benign (0.227); catalogued as COSV60209283, COSV60210213; called by muse, mutect2, varscan2
- TTN | c.14972G>A p.R4991Q (on ENST00000591111; = p.R4064Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | PolyPhen possibly damaging (0.69); catalogued as rs146847928, COSV60102722; called by muse, mutect2, varscan2
- TUBA1B | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV60137911; called by muse, mutect2, varscan2
- TUBA1B | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.218); catalogued as COSV60137252; called by muse, mutect2, varscan2
- TUBB2A | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100373786; called by muse, mutect2, varscan2
- TULP4 | c.3115C>G p.Q1039E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV100893223; called by muse, mutect2
- UBAP2L | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV55177317; called by muse, mutect2, varscan2
- UBAP2L | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV55168476, COSV55173895, COSV55177354, COSV99670916; called by muse, mutect2, varscan2
- UBE2O | c.1606C>G p.R536G | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60065664; called by muse, mutect2, varscan2
- UBE3A | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.073); catalogued as COSV51668628; called by muse, mutect2, varscan2
- UBE3C | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs754175914, COSV61954781; called by muse, mutect2, varscan2
- UBR4 | c.379-1G>A p.X127_splice | Splice Site (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100920465; called by muse, mutect2
- UGGT2 | c.4194G>C p.K1398N | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100948512; called by muse, mutect2
- UNC5C | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); catalogued as COSV71661248; called by muse, mutect2, varscan2
- UROC1 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV52036422; called by muse, mutect2, varscan2
- USP17L2 | c.245T>A p.L82H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61556255; called by muse, mutect2, varscan2
- USP31 | c.2668C>A p.H890N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.395); catalogued as rs1393361072, COSV54854762; called by muse, mutect2, varscan2
- USP7 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61216164; called by muse, mutect2
- VAV3 | c.2301G>C p.K767N | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100580443, COSV58388017; called by muse, mutect2, varscan2
- VAV3 | c.277C>A p.L93I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV64070398; called by muse, mutect2, varscan2
- VEZF1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV51969576; called by muse, mutect2, varscan2
- VPS13B | c.11787G>C p.Q3929H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100663351, COSV62150607; called by muse, mutect2, varscan2
- WBP4 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV65274371; called by muse, mutect2, varscan2
- WDR33 | c.2440C>T p.H814Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.091); catalogued as COSV59253107; called by muse, mutect2, varscan2
- WDR33 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59253118; called by muse, mutect2, varscan2
- WDR35 | c.1723C>T p.R575* (on ENST00000345530 / NM_001006657.2; = p.R564* on NM_020779.4) | Nonsense Mutation (SNP) | VAF 42/129 reads (33%) | catalogued as rs367810877; called by muse, mutect2, varscan2
- WFIKKN2 | c.1717C>T p.L573F | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.235); catalogued as COSV60958126, COSV60959595; called by muse, mutect2, varscan2
- WNT2B | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV56675934; called by muse, mutect2, varscan2
- YME1L1 | c.2278G>C p.E760Q (on ENST00000326799 / NM_139312.3; = p.E703Q on NM_014263.4) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV58760595; called by muse, mutect2, varscan2
- YWHAQ | c.279C>G p.I93M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.487); catalogued as COSV53004121; called by muse, mutect2
- ZBTB39 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.193); catalogued as COSV55630122; called by muse, mutect2, varscan2
- ZBTB43 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 52/92 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV65095084; called by muse, mutect2, varscan2
- ZC2HC1A | c.676C>G p.H226D | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV55670259, COSV55671149; called by muse, mutect2, varscan2
- ZDBF2 | c.2993C>G p.S998* | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV65621904; called by muse, mutect2
- ZFAND1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV55107558; called by muse, mutect2, varscan2
- ZFP28 | c.2606A>G p.*869Wext*8 | Nonstop Mutation (SNP) | VAF 24/126 reads (19%) | catalogued as COSV100019341; called by muse, mutect2, varscan2
- ZFYVE16 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV62016596; called by muse, mutect2, varscan2
- ZGRF1 | c.4225G>A p.D1409N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV71393540; called by muse, mutect2, varscan2
- ZGRF1 | c.2495T>A p.L832Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as rs957303673, COSV52202191; called by muse, mutect2, varscan2
- ZHX3 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100476110, COSV58386403; called by muse, mutect2, varscan2
- ZHX3 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV58386412; called by muse, mutect2, varscan2
- ZNF180 | c.2038C>G p.Q680E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.22); catalogued as COSV55422767; called by muse, mutect2, varscan2
- ZNF202 | c.1855A>G p.K619E | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60247818; called by muse, mutect2, varscan2
- ZNF205 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54622113; called by muse, mutect2, varscan2
- ZNF251 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99478198; called by muse, mutect2, varscan2
- ZNF254 | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100741527; called by muse, mutect2, varscan2
- ZNF267 | c.1598C>G p.S533* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100339567; called by muse, mutect2, varscan2
- ZNF318 | c.2989G>C p.E997Q | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV58935165; called by muse, mutect2, varscan2
- ZNF41 | c.1516C>G p.H506D | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV57444306; called by muse, mutect2, varscan2
- ZNF441 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV63540454; called by muse, mutect2, varscan2
- ZNF445 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV68539293; called by muse, mutect2, varscan2
- ZNF470 | c.182C>G p.S61* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | catalogued as COSV100401123; called by muse, mutect2
- ZNF483 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 50/111 reads (45%) | catalogued as COSV100492686; called by muse, mutect2, varscan2
- ZNF511 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV62920381; called by muse, mutect2, varscan2
- ZNF563 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53371406; called by muse, mutect2, varscan2
- ZNF580 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.19); catalogued as COSV99553052; called by muse, mutect2
- ZNF586 | c.845G>C p.R282T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV66972585; called by muse, mutect2, varscan2
- ZNF609 | c.3930G>C p.K1310N | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58587094; called by muse, mutect2, varscan2
- ZNF750 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53959616, COSV53962745; called by muse, mutect2
- ZNF76 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs762018098, COSV57354785; called by muse, mutect2, varscan2
- ZNF774 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1193811081, COSV62980572; called by muse, mutect2, varscan2
- ZPBP2 | c.586G>C p.E196Q (on ENST00000348931 / NM_199321.3; = p.E174Q on NM_198844.3) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV62375468; called by muse, mutect2, varscan2
- ZSCAN4 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV56594083; called by muse, mutect2, varscan2
- ZZEF1 | c.6023G>C p.R2008T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as COSV67559043; called by muse, mutect2, varscan2
- ASAH2 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ATP4A | c.2812G>T p.E938* | Nonsense Mutation (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- CAMTA1 | c.4201_4216del p.A1401Kfs*32 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- CEP164 | c.3212del p.G1071Efs*38 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- PCDHGC3 | c.808del p.D270Ifs*28 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.74T>A p.L25* | Nonsense Mutation (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- PRAMEF17 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TMEM87A | c.1651dup p.R551Kfs*14 | Frame Shift Ins (INS) | VAF 29/92 reads (32%) | called by pindel, varscan2
- TRAV1-1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- WASHC2A | c.3211G>A p.D1071N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZNHIT3 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.360G>A p.E120= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV58445278; called by muse, mutect2, varscan2
- ADGRD1 | c.1971C>T p.L657= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV55451542; called by muse, mutect2, varscan2
- AHCYL1 | c.90C>T p.F30= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100874640; called by muse, mutect2, varscan2
- AHNAK2 | c.9018G>A p.P3006= | Silent (SNP) | VAF 142/282 reads (50%) | catalogued as rs372139093, COSV60913771; called by muse, mutect2, varscan2
- ALDH3A2 | c.1053C>T p.F351= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV104385335, COSV51565652; called by muse, mutect2, varscan2
- ALDH7A1 | c.852G>C p.L284= | Silent (SNP) | VAF 36/110 reads (33%) | catalogued as rs747107627, COSV68629714; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALG12 | c.903C>G p.L301= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV58207911; called by muse, mutect2
- APBB3 | c.1197C>T p.L399= (on ENST00000357560 / NM_133173.2; = p.L406= on NM_006051.3) | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV60053475; called by muse, mutect2, varscan2
- ARHGEF37 | c.1953G>A p.Q651= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV61369537; called by muse, mutect2, varscan2
- ASCC3 | c.1353C>G p.L451= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV61226715, COSV61231339; called by muse, mutect2, varscan2
- B3GALNT2 | c.1041G>C p.T347= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV64004361; called by muse, mutect2, varscan2
- BBS12 | c.210C>T p.L70= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100044914, COSV58562663; called by muse, mutect2, varscan2
- BCAR3 | c.102C>A p.L34= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV53077307, COSV99550482; called by muse, mutect2, varscan2
- BDKRB2 | c.957C>T p.F319= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV60016012; called by muse, mutect2, varscan2
- BRIP1 | c.1242G>A p.Q414= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs1257200897, COSV52004532; called by muse, mutect2, varscan2
- C11orf49 | c.195C>T p.F65= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as COSV53568536; called by muse, varscan2
- C6orf118 | c.531C>A p.L177= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV57817148; called by muse, mutect2, varscan2
- CACNA1A | c.456C>T p.I152= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs865835761, COSV64198807; called by muse, mutect2, varscan2
- CALN1 | c.645G>C p.R215= (on ENST00000329008 / NM_001017440.3; = p.R257= on NM_031468.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV61123899; called by muse, mutect2, varscan2
- CC2D1B | c.2349C>T p.F783= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV52561644; called by muse, mutect2
- CCT7 | c.87C>T p.C29= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV57821470; called by muse, mutect2, varscan2
- CD33 | c.444C>T p.L148= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs767772786, COSV51803426; called by muse, mutect2, varscan2
- CERS3 | c.912C>T p.L304= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52571782; called by muse, mutect2, varscan2
- CES2 | c.753C>T p.I251= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV57697401; called by muse, mutect2, varscan2
- CETP | c.1029C>G p.L343= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV99569897; called by muse, mutect2
- CFAP221 | c.2013G>C p.L671= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV54660112; called by muse, mutect2, varscan2
- CLBA1 | c.957C>G p.L319= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV66348293; called by muse, mutect2, varscan2
- CLDN9 | c.543C>G p.L181= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs1386235464, COSV60911291; called by muse, mutect2, varscan2
- CLEC2L | c.603G>C p.L201= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs374282277; called by muse, varscan2
- CLPB | c.1662G>A p.R554= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV53631626; called by muse, varscan2
- CLUL1 | c.264G>C p.L88= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV58112895; called by muse, mutect2, varscan2
- COL17A1 | c.1230G>C p.L410= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100793223, COSV62226154; called by muse, mutect2, varscan2
- COL22A1 | c.3372C>T p.L1124= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs1265469442, COSV57348798; called by muse, mutect2, varscan2
- COPG1 | c.162C>T p.L54= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV59115608; called by muse, mutect2, varscan2
- CPSF1 | c.2256C>G p.G752= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV58234705; called by muse, mutect2, varscan2
- CST9L | c.443G>A p.*148= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100980833; called by muse, mutect2, varscan2
- CYP1B1 | c.1584C>A p.L528= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV52227529; called by muse, mutect2, varscan2
- CYP26B1 | c.1263G>A p.R421= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV50013350; called by muse, mutect2, varscan2
- DHRS9 | c.423C>T p.L141= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV59140860; called by muse, varscan2
- DLEC1 | c.540G>A p.E180= | Silent (SNP) | VAF 13/24 reads (54%) | catalogued as COSV57303339; called by muse, mutect2, varscan2
- DLG5 | c.4146C>T p.I1382= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs568757709, COSV64947676; called by muse, mutect2, varscan2
- DPY19L2 | c.849C>T p.F283= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100116584; called by muse, mutect2, varscan2
- DUSP8 | c.18C>T p.L6= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV59030813; called by muse, mutect2, varscan2
- DYSF | c.4071C>T p.L1357= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as rs773240314, COSV99250019; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2
- EIF2AK3 | c.2877G>C p.V959= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV57550241; called by muse, mutect2, varscan2
- ENPEP | c.1644C>T p.N548= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs201367483, COSV54448664; called by muse, mutect2, varscan2
- F2 | c.279G>A p.A93= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs778280660, COSV61316709; called by muse, mutect2, varscan2
- F5 | c.3555C>G p.V1185= | Silent (SNP) | VAF 80/167 reads (48%) | catalogued as COSV63126214; called by muse, mutect2, varscan2
- FAM71A | c.364C>T p.L122= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV54236475; called by muse, mutect2, varscan2
- FBXL19 | c.165C>T p.F55= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs1218075785, COSV100608658; called by muse, mutect2
- FGD2 | c.1704G>T p.V568= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV51465010; called by muse, mutect2, varscan2
- FRAS1 | c.6858C>T p.F2286= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV53629912; called by muse, mutect2, varscan2
- GAN | c.894C>G p.L298= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs776812286, COSV73721169; called by muse, mutect2, varscan2
- GCKR | c.1716C>G p.P572= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV99268812; called by muse, varscan2
- GFOD2 | c.138G>A p.E46= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV52059028; called by muse, mutect2, varscan2
- GLRA2 | c.1074G>A p.Q358= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV54344780; called by muse, mutect2, varscan2
- GMPR | c.426G>A p.V142= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as COSV52474350; called by muse, mutect2, varscan2
- GMPR2 | c.504C>T p.L168= (on ENST00000355299 / NM_001351022.2; = p.L186= on NM_016576.5) | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs1377538489, COSV51661198; called by muse, mutect2, varscan2
- GOLGA1 | c.1434G>C p.V478= | Silent (SNP) | VAF 31/57 reads (54%) | catalogued as rs1411883687, COSV63024160, COSV63024170; called by muse, mutect2, varscan2
- GPD1L | c.399C>G p.L133= | Silent (SNP) | VAF 37/81 reads (46%) | catalogued as COSV56989563, COSV56991216; called by muse, mutect2, varscan2
- GPR55 | c.111C>G p.L37= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV67408224; called by muse, mutect2, varscan2
- GRIN1 | c.801C>T p.L267= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs1432781527, COSV59298969; called by muse, mutect2, varscan2
- GTF3C3 | c.2106C>G p.L702= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV55833480; called by muse, mutect2, varscan2
- GZMB | c.408G>A p.V136= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV99362224; called by muse, mutect2, varscan2
- H2AC20 | c.303C>T p.V101= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs782127378, COSV58612668; called by muse, mutect2, varscan2
- H2BC11 | c.264G>C p.S88= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs761516102, COSV60362418; called by muse, mutect2, varscan2
- HDAC1 | c.909C>T p.Y303= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs750474499, COSV61482242; called by muse, mutect2, varscan2
- HDGF | c.420C>T p.V140= | Silent (SNP) | VAF 114/237 reads (48%) | catalogued as COSV61977285; called by muse, mutect2, varscan2
- HPGD | c.213G>A p.L71= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs1456873872, COSV56663630; called by muse, mutect2, varscan2
- HSPA12B | c.714C>A p.L238= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs1016046849, COSV54768261; called by muse, mutect2, varscan2
- HTR1A | c.705G>A p.K235= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as COSV60502017; called by muse, mutect2, varscan2
- IFNA13 | c.516C>T p.I172= | Silent (SNP) | VAF 97/256 reads (38%) | catalogued as COSV71924538; called by muse, mutect2, varscan2
- IFNGR1 | c.1428G>A p.L476= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV62992401; called by muse, mutect2, varscan2
- IGFALS | c.978C>T p.I326= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV51907409; called by muse, varscan2
- IGFBP5 | c.441G>A p.L147= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99288821; called by muse, mutect2, varscan2
- IGKV2D-28 | c.327G>A p.G109= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101494552; called by mutect2, varscan2
- IL17A | c.45G>A p.L15= | Silent (SNP) | VAF 72/219 reads (33%) | catalogued as COSV60685108; called by muse, mutect2, varscan2
- IL1R1 | c.21T>C p.L7= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV52107188; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1029T>C p.S343= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV61169457; called by muse, mutect2, varscan2
- IQGAP3 | c.1506G>C p.L502= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV63253307; called by muse, mutect2, varscan2
- IQGAP3 | c.516C>T p.L172= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs1282968649, COSV100752089; called by muse, mutect2, varscan2
- IVNS1ABP | c.1110C>T p.L370= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV62251634; called by muse, mutect2, varscan2
- KCNC3 | c.1482C>T p.F494= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs762941392, COSV65388213; called by muse, mutect2, varscan2
- KCNH4 | c.933C>T p.I311= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as rs753377353, COSV52919780; called by muse, mutect2, varscan2
- KDM1A | c.1359G>A p.E453= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1198769232, COSV63089174; called by muse, mutect2, varscan2
- KDM3A | c.1617C>T p.I539= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs758070952, COSV57223869; called by muse, mutect2, varscan2
- KIF24 | c.1944G>A p.V648= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs879212988, COSV61456979; called by muse, mutect2, varscan2
- KIFC2 | c.382C>T p.L128= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs777824599, COSV56762122; called by muse, mutect2, varscan2
- KRIT1 | c.1593C>G p.L531= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV60669445; called by muse, mutect2, varscan2
- KRT71 | c.1062C>T p.L354= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV57292057; called by muse, mutect2, varscan2
- LAMB3 | c.2787G>A p.L929= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV50524058; called by muse, mutect2
- LRP1 | c.12906C>G p.R4302= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99674823; called by muse, mutect2
- MAGI3 | c.2214C>T p.F738= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV56840641; called by muse, mutect2, varscan2
- MANF | c.111G>C p.L37= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV56549507, COSV99809757; called by muse, mutect2, varscan2
- MFSD2A | c.885C>T p.F295= (on ENST00000372809 / NM_001136493.3; = p.F282= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV65686184; called by muse, varscan2
- MIEF1 | c.666C>T p.D222= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs1201235658, COSV57479909; called by muse, mutect2, varscan2
- MMP20 | c.465G>C p.L155= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV52776987; called by muse, mutect2, varscan2
- MUC4 | c.13395C>T p.L4465= (on ENST00000463781 / NM_018406.7; = p.L229= on NM_004532.6) | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs376767009; called by muse, mutect2, varscan2
- MYO1E | c.1446C>T p.L482= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV55691592, COSV55692252; called by muse, mutect2, varscan2
- NDNF | c.1701C>T p.F567= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV65633311, COSV65634264, COSV65634402; called by muse, mutect2, varscan2
- NDOR1 | c.819C>G p.L273= | Silent (SNP) | VAF 13/20 reads (65%) | catalogued as COSV61289168; called by muse, mutect2, varscan2
- NDOR1 | c.1308C>T p.L436= (on ENST00000371521 / NM_001144026.3; = p.L429= on NM_014434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as rs1370531701, COSV61288555, COSV61289180; called by muse, varscan2
- NDUFB5 | c.375C>T p.F125= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV52021130; called by muse, mutect2, varscan2
- NFX1 | c.1728C>T p.C576= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV59311901; called by muse, mutect2
- NLRP13 | c.63G>A p.L21= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV61623179; called by muse, mutect2, varscan2
- NLRX1 | c.2277C>T p.L759= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV52706953; called by muse, mutect2, varscan2
- NMNAT2 | c.804C>G p.V268= | Silent (SNP) | VAF 77/173 reads (45%) | catalogued as COSV54270304; called by muse, mutect2, varscan2
- NPHS1 | c.681C>G p.P227= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV62289091; called by muse, mutect2, varscan2
- NPR2 | c.1581C>A p.L527= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV61313124; called by muse, mutect2, varscan2
- NRXN3 | c.1539C>T p.L513= (on ENST00000335750 / NM_001330195.2; = p.L140= on NM_004796.6) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs368322773; called by muse, mutect2, varscan2
- NTM | c.390C>T p.L130= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100867665, COSV66179769; called by muse, mutect2
- OR5P2 | c.477C>T p.F159= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV61490756, COSV61490963; called by muse, mutect2, varscan2
- ORMDL1 | c.372C>T p.F124= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV57877288; called by muse, mutect2, varscan2
- OVGP1 | c.1011C>T p.F337= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV63859246; called by muse, mutect2, varscan2
- OVOL1 | c.312G>A p.K104= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100256755; called by muse, mutect2
- PAQR7 | c.588G>A p.Q196= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV65352035; called by muse, mutect2, varscan2
- PCDHA12 | c.2139C>T p.L713= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV56527978; called by muse, mutect2, varscan2
- PCDHA7 | c.192C>T p.F64= | Silent (SNP) | VAF 84/165 reads (51%) | catalogued as COSV65346073; called by muse, mutect2, varscan2
- PCDHB10 | c.1467G>A p.S489= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs782469015, COSV53381572; called by muse, mutect2, varscan2
- PCDHB9 | c.2106C>T p.L702= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as rs1462337272; called by muse, mutect2
- PCDHGA7 | c.1626C>T p.L542= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as COSV53992755; called by muse, mutect2, varscan2
- PCNT | c.189C>T p.L63= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV52450898; called by muse, mutect2, varscan2
- PCSK1 | c.363C>T p.F121= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV60736610; called by muse, mutect2, varscan2
- PLCXD2 | c.318G>A p.L106= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV67341377; called by muse, mutect2, varscan2
- PLEKHA3 | c.705C>T p.L235= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV52295586, COSV99317524; called by muse, mutect2, varscan2
- PPARA | c.396C>G p.L132= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV53078921, COSV53080262; called by muse, mutect2, varscan2
- PRAMEF12 | c.207G>T p.L69= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100743407, COSV63216058; called by muse, mutect2, varscan2
- PRDM13 | c.2103C>T p.G701= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV65030398; called by muse, mutect2, varscan2
- PRKDC | c.4077G>A p.L1359= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV58045152, COSV58058861; called by muse, mutect2, varscan2
- PSIP1 | c.30C>T p.L10= | Silent (SNP) | VAF 57/155 reads (37%) | catalogued as rs139542300; called by muse, mutect2, varscan2
- PTPRN2 | c.2871G>A p.L957= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs144485708; called by muse, mutect2, varscan2
- RAB32 | c.201C>G p.L67= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV62249374; called by muse, mutect2, varscan2
- RB1CC1 | c.4167C>T p.V1389= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV50259766; called by muse, mutect2, varscan2
- RIN3 | c.1956G>A p.K652= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs1446466242, COSV53652641; called by muse, mutect2, varscan2
- RLBP1 | c.258G>A p.E86= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV51528817; called by muse, mutect2, varscan2
- RLF | c.4467G>A p.R1489= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV65652553; called by muse, mutect2, varscan2
- RRP9 | c.1281C>T p.L427= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV51755557; called by muse, mutect2, varscan2
- RTTN | c.117C>T p.L39= | Silent (SNP) | VAF 30/130 reads (23%) | catalogued as COSV55348759; called by muse, mutect2, varscan2
- RYR2 | c.14226C>T p.H4742= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100768580; called by muse, mutect2
- SCN5A | c.3093C>T p.G1031= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs755980331, COSV61133084; ClinVar: uncertain significance; called by muse, mutect2
- SDSL | c.666C>T p.I222= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs754528924, COSV61884991; called by muse, mutect2, varscan2
- SETDB1 | c.1860G>A p.K620= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54988883; called by muse, mutect2, varscan2
- SF3B2 | c.1899G>A p.L633= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV100488295; called by muse, mutect2, varscan2
- SFTPA1 | c.477C>T p.G159= | Silent (SNP) | VAF 42/178 reads (24%) | catalogued as rs773848066, COSV64867361; called by muse, mutect2, varscan2
- SHANK1 | c.2028C>T p.F676= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV53253654; called by muse, mutect2, varscan2
- SHOC2 | c.651C>T p.L217= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV54623377; called by muse, mutect2, varscan2
- SLC12A3 | c.2232G>A p.K744= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV52637184; called by muse, mutect2, varscan2
- SLC22A2 | c.1662G>A p.L554= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV65270780; called by muse, mutect2
- SLC25A19 | c.962G>A p.*321= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs1201171919, COSV55468688; called by muse, mutect2, varscan2
- SLC26A7 | c.927C>T p.I309= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV52599586; called by muse, mutect2, varscan2
- SLC36A2 | c.354G>A p.K118= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV58864255; called by muse, mutect2, varscan2
- SORL1 | c.3516C>A p.R1172= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV52758596; called by muse, mutect2, varscan2
- SPIRE1 | c.1107C>G p.L369= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV59159605; called by muse, mutect2, varscan2
- SPRY2 | c.636G>A p.V212= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV65701621; called by muse, mutect2, varscan2
- SUPT6H | c.3390G>A p.L1130= | Silent (SNP) | VAF 63/110 reads (57%) | catalogued as rs1426080919, COSV58929675; called by muse, mutect2, varscan2
- SVEP1 | c.2982G>C p.L994= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100237456; called by muse, mutect2, varscan2
- SYNPO | c.1440C>T p.V480= (on ENST00000394243 / NM_001166208.2; = p.V236= on NM_007286.6) | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as COSV56941621; called by muse, mutect2, varscan2
- TACC1 | c.2094G>A p.L698= | Silent (SNP) | VAF 13/175 reads (7%) | catalogued as COSV52526902; called by muse, mutect2
- TCF7 | c.907C>T p.L303= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV58658012; called by muse, mutect2, varscan2
- TEX26 | c.672G>A p.L224= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV66840340; called by muse, mutect2, varscan2
- TGFBR3 | c.1504C>T p.L502= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV53028773; called by muse, mutect2, varscan2
- THEM4 | c.522C>T p.I174= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs747684350, COSV64295183; called by muse, mutect2, varscan2
- TLL2 | c.621C>T p.F207= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1157306023, COSV63574285; called by muse, mutect2, varscan2
- TNFRSF14 | c.282G>T p.L94= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV63187647; called by muse, mutect2, varscan2
- TONSL | c.717C>T p.F239= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV68048910; called by muse, mutect2, varscan2
- TPP1 | c.1056C>T p.L352= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV54993454; called by muse, mutect2, varscan2
- TPPP3 | c.225C>T p.F75= | Silent (SNP) | VAF 73/179 reads (41%) | catalogued as COSV52084456; called by muse, mutect2, varscan2
- TRIM17 | c.48C>T p.C16= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs780634687, COSV54383506; called by muse, mutect2, varscan2
- TRPM5 | c.3051C>T p.L1017= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1354432335, COSV50151352; called by muse, mutect2
- TTN | c.50727C>T p.F16909= (on ENST00000591111; = p.F9485= on NM_003319.4) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs1248662230, COSV60210162; called by muse, mutect2, varscan2
- UBLCP1 | c.144C>G p.L48= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as COSV57144014; called by muse, mutect2, varscan2
- UBR4 | c.783G>A p.L261= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs1177768687, COSV64394947; called by muse, mutect2, varscan2
- USH2A | c.927G>T p.P309= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs751443710, COSV56338933, COSV56404031; called by muse, mutect2, varscan2
- USP8 | c.1365C>T p.L455= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs139912757; called by muse, mutect2, varscan2
- WDR54 | c.264C>T p.L88= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV51965081, COSV51965430; called by muse, mutect2, varscan2
- WDSUB1 | c.90G>A p.L30= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV63067746; called by muse, mutect2, varscan2
- ZBTB22 | c.351C>T p.L117= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as COSV56471450; called by muse, mutect2, varscan2
- ZBTB6 | c.1191C>T p.L397= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV65410388; called by muse, mutect2, varscan2
- ZNF10 | c.1494C>T p.F498= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV50213569; called by muse, mutect2, varscan2
- ZNF331 | c.1224G>A p.V408= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs989237430, COSV53478479; called by muse, mutect2, varscan2
- ZNF362 | c.1200G>A p.V400= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV65031740; called by muse, mutect2, varscan2
- ZNF425 | c.174C>T p.I58= | Silent (SNP) | VAF 88/233 reads (38%) | catalogued as COSV65201913, COSV65202015; called by muse, mutect2, varscan2
- ZNF507 | c.147G>A p.Q49= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1210781187, COSV61332468; called by muse, mutect2, varscan2
26 further variants in this file (0 protein-altering or splice-affecting, 2 silent, 24 other) are not listed here.
